Somatic mutation profile of tumor specimen TCGA-DM-A28G-01A (aliquot TCGA-DM-A28G-01A-11D-A16V-10) from TCGA case TCGA-DM-A28G, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 75.7 years (27,641 days).
Specimen TCGA-DM-A28G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba596ee9-1846-4ca9-8976-be2b1ea8132f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A28G-10A (Blood Derived Normal), aliquot TCGA-DM-A28G-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/647849fd-60a0-4601-ab4f-8114bd28ea43

The open-access MAF lists 135 somatic variants for this specimen: 94 protein-altering or splice-affecting, 40 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 40, Frame Shift Ins 4, Nonsense Mutation 4, Splice Site 3, 5'Flank 1, Splice Region 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYSF | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149827237, CM053209; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1514G>A p.R505H (on ENST00000281708 / NM_001349798.2; = p.R425H on NM_018315.5) | Missense Mutation (SNP) | VAF 35/107 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 28/73 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV61005066; called by muse, mutect2, varscan2
- ADGRL2 | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV54687590; called by muse, mutect2, varscan2
- AKR1D1 | c.764C>A p.A255E | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54340671; called by muse, varscan2
- AKR1D1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs143101649; called by muse, varscan2
- ANKIB1 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1221768191, COSV56065767; called by muse, mutect2, varscan2
- ANKS1B | c.1207G>T p.G403* | Nonsense Mutation (SNP) | VAF 77/170 reads (45%) | catalogued as COSV61374272; called by mutect2, varscan2
- ANO3 | c.2171A>C p.K724T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV56807405; called by muse, mutect2, varscan2
- ATP2B2 | c.2380G>T p.D794Y (on ENST00000352432; = p.D760Y on NM_001683.5) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59506745; called by muse, mutect2, varscan2
- ATP5F1B | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51643180; called by muse, mutect2, varscan2
- ATP6V1G2 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as COSV58215138; called by muse, mutect2, varscan2
- CCDC9B | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as COSV66876185; called by muse, mutect2, varscan2
- CDKL2 | c.1127G>A p.S376N | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100277181; called by muse, mutect2, varscan2
- CFH | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV62778090, COSV62778758; called by muse, mutect2, varscan2
- COL9A1 | c.1557+1G>A p.X519_splice | Splice Site (SNP) | VAF 20/68 reads (29%) | catalogued as COSV57892537; called by muse, mutect2, varscan2
- CPLX4 | c.24_26del p.M8del | In Frame Del (DEL) | VAF 21/71 reads (30%) | catalogued as rs779130588; called by mutect2, pindel, varscan2
- DBH | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368994366; called by muse, mutect2, varscan2
- DBR1 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV99604623; called by muse, mutect2, varscan2
- DCAF5 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as rs1379174992, COSV58462928; called by muse, mutect2, varscan2
- DNAH11 | c.8386C>T p.P2796S | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV100180679; called by muse, mutect2, varscan2
- DPP9 | c.1090G>A p.A364T (on ENST00000598800; = p.A393T on NM_139159.5) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as rs774925863, COSV53594176; called by muse, mutect2
- E4F1 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs761050026, COSV100066076, COSV57039450; called by muse, mutect2, varscan2
- EPHA3 | c.237C>A p.N79K | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60725772; called by muse, mutect2, varscan2
- EPHX1 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV99689197; called by muse, mutect2, varscan2
- EXPH5 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1307609225; called by muse, mutect2
- FASN | c.6146G>A p.R2049Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.067); catalogued as rs373838349; called by muse, mutect2, varscan2
- FAT4 | c.10832A>G p.D3611G | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1258096790, COSV100630035; called by muse, mutect2, varscan2
- FCGBP | c.1217C>T p.T406M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.082); catalogued as rs377164847; called by muse, mutect2, varscan2
- GABPA | c.1148A>G p.D383G | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100702515; called by muse, mutect2, varscan2
- GLRB | c.1199T>A p.V400D | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.406); catalogued as COSV52422034; called by muse, mutect2, varscan2
- GPRC5D | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV57433419; called by muse, mutect2, varscan2
- GRID1 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV60050913; called by muse, mutect2, varscan2
- H4C13 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.927); catalogued as COSV60695141; called by muse, mutect2, varscan2
- HELB | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 43/108 reads (40%) | catalogued as rs370199105; called by muse, mutect2, varscan2
- HTR3E | c.1070C>T p.P357L (on ENST00000415389 / NM_001256613.1; = p.P372L on NM_182589.2) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs200919072, COSV58945851, COSV58946928; called by muse, mutect2, varscan2
- KALRN | c.8070T>G p.I2690M (on ENST00000360013 / NM_001024660.4; = p.I993M on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99362894; called by muse, mutect2, varscan2
- KCNH3 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57792726; called by muse, mutect2, varscan2
- KCNIP4 | c.76C>A p.Q26K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.09); catalogued as COSV100749723; called by muse, mutect2, varscan2
- KIAA2026 | c.3824G>A p.R1275K | Missense Mutation (SNP) | VAF 71/200 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67357576; called by muse, mutect2, varscan2
- KIF3C | c.1711C>T p.R571W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1283685560, COSV53101685; called by muse, mutect2, varscan2
- LMO7 | c.875C>T p.A292V (on ENST00000357063; = p.A307V on NM_005358.5) | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs375314137; called by muse, mutect2, varscan2
- LRP2 | c.1621G>A p.A541T | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99790132; called by muse, mutect2, varscan2
- LRRC8C | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); catalogued as COSV65000959; called by muse, mutect2, varscan2
- LRRTM3 | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as rs1406857994, COSV63666154; called by muse, mutect2, varscan2
- MRPL39 | c.811A>G p.R271G | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV100221092; called by muse, mutect2, varscan2
- MS4A1 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs143807889; called by mutect2, varscan2
- MTF2 | c.798-1G>A p.X266_splice | Splice Site (SNP) | VAF 21/91 reads (23%) | catalogued as COSV64772098; called by muse, mutect2, varscan2
- MTMR4 | c.2360C>T p.T787I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.005); catalogued as rs1176119970, COSV100051412; called by muse, mutect2, varscan2
- MUC16 | c.36547C>T p.R12183W | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs200670536, COSV67490882; called by muse, mutect2, varscan2
- MYH3 | c.5099G>A p.R1700Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747006068, COSV56862977; called by muse, mutect2, varscan2
- MYO3A | c.1208G>A p.S403N | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56347561; called by muse, mutect2, varscan2
- MYO3A | c.2711C>A p.A904E | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.102); catalogued as COSV56347576; called by muse, mutect2, varscan2
- NALCN | c.2966G>A p.R989Q | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756904207, COSV51934611; called by muse, mutect2, varscan2
- NCKAP5L | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs1007843254, COSV100259182; called by muse, mutect2, varscan2
- NLGN1 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.22); catalogued as rs1244665153, COSV64345721; called by muse, mutect2, varscan2
- NLRC3 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473124254, COSV57090364, COSV57092707; called by muse, mutect2, varscan2
- NLRP4 | c.2647C>A p.L883M | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV56722604; called by muse, mutect2, varscan2
- OR13F1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs191015152, COSV58251628; called by muse, mutect2, varscan2
- PALD1 | c.1284C>A p.Y428* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs756753364, COSV54978546; called by muse, mutect2, varscan2
- PAX3 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.302); catalogued as rs770087251, CD102011, COSV60586905; called by muse, mutect2, varscan2
- PCDH15 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs752256957, COSV57340947, COSV57387588; called by muse, mutect2, varscan2
- PCDHA11 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56485690; called by muse, mutect2
- PTCHD4 | c.2185T>G p.C729G | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); catalogued as COSV100261561; called by mutect2, varscan2
- PTPRT | c.2863C>T p.R955W | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs754546663, COSV61974226; called by muse, mutect2, varscan2
- RIMS2 | c.1850G>C p.C617S (on ENST00000666250 / NM_001348490.2; = p.C425S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs764327980, COSV51720955, COSV99165608; called by muse, mutect2, varscan2
- RP1 | c.6157G>C p.D2053H | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV55109856, COSV99608767; called by muse, mutect2, varscan2
- SACS | c.6306G>T p.L2102F | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as COSV66546479; called by muse, mutect2, varscan2
- SLCO4A1 | c.1497C>A p.N499K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.314); catalogued as COSV53893676; called by muse, mutect2, varscan2
- SMARCA1 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64411408; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | PolyPhen benign (0.021); catalogued as rs1449055625, COSV56572582; called by muse, mutect2
- TAF6L | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs138817605; called by muse, mutect2, varscan2
- TFR2 | c.849G>A p.K283= | Splice Region (SNP) | VAF 19/58 reads (33%) | catalogued as COSV56156324; called by muse, mutect2, varscan2
- TGFBR3 | c.2320A>T p.I774F | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV53030860; called by muse, mutect2, varscan2
- TTC29 | c.1268G>T p.S423I | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV57285084; called by muse, mutect2, varscan2
- TTN | c.6718G>C p.D2240H (on ENST00000591111; = p.D2194H on NM_003319.4) | Missense Mutation (SNP) | VAF 15/106 reads (14%) | PolyPhen probably damaging (0.999); catalogued as COSV100628494; called by muse, mutect2, varscan2
- VARS2 | c.2313+2T>C p.X771_splice | Splice Site (SNP) | VAF 30/82 reads (37%) | catalogued as COSV58914531; called by muse, mutect2, varscan2
- XIRP2 | c.9117C>G p.I3039M (on ENST00000628543; = p.I3214M on NM_152381.6) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV54731833; called by muse, mutect2, varscan2
- XPO4 | c.1806T>A p.D602E | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV55012694; called by muse, mutect2, varscan2
- YEATS2 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.265); catalogued as COSV59372053; called by muse, mutect2, varscan2
- ZBTB7C | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs750842250, COSV59690887; called by muse, varscan2
- ZFP82 | c.888C>A p.H296Q | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.535); catalogued as COSV67566691; called by muse, mutect2, varscan2
- ZFYVE9 | c.3374G>T p.G1125V | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99820672; called by muse, mutect2, varscan2
- ZNF20 | c.515A>T p.D172V | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100503156; called by muse, mutect2, varscan2
- ZNF329 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (1); PolyPhen probably damaging (0.93); catalogued as rs768654317, COSV63771807; called by muse, mutect2, varscan2
- ZNF714 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as COSV52514964, COSV52515398; called by muse, mutect2, varscan2
- ZNF783 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); catalogued as rs1392063469, COSV65186751; called by muse, mutect2, varscan2
- ZZEF1 | c.6280G>A p.A2094T | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV67560083; called by muse, mutect2, varscan2
- LUZP1 | c.2020dup p.V674Gfs*16 | Frame Shift Ins (INS) | VAF 84/300 reads (28%) | called by mutect2, pindel, varscan2
- MROH5 | c.1511dup p.F505Vfs*49 | Frame Shift Ins (INS) | VAF 28/59 reads (47%) | called by mutect2, pindel, varscan2
- TBX3 | c.2141_2142del p.K714Rfs*15 (on ENST00000257566 / NM_016569.4; = p.K694Rfs*15 on NM_005996.4) | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | called by mutect2, varscan2
- TBX3 | c.438dup p.A147Sfs*13 | Frame Shift Ins (INS) | VAF 39/123 reads (32%) | called by mutect2, pindel, varscan2
- ZNF436 | c.634_637dup p.Q213Pfs*14 | Frame Shift Ins (INS) | VAF 24/77 reads (31%) | called by mutect2, pindel, varscan2
- ABCB1 | c.663C>T p.I221= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV55962549; called by muse, mutect2, varscan2
- ACTR10 | c.396A>G p.G132= | Silent (SNP) | VAF 74/226 reads (33%) | catalogued as COSV99581349; called by mutect2, varscan2
- ALKBH4 | c.156C>T p.T52= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs374535640; called by muse, mutect2, varscan2
- APBA2 | c.1566G>T p.V522= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV67105668; called by muse, mutect2, varscan2
- ARAP2 | c.3666T>C p.I1222= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV100395210; called by muse, mutect2
- ASH1L | c.7617A>C p.L2539= (on ENST00000368346 / NM_001366177.2; = p.L2534= on NM_018489.3) | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV64213258; called by muse, mutect2, varscan2
- C1QTNF4 | c.243G>A p.T81= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs781609630, COSV56784488; called by muse, mutect2, varscan2
- CSMD1 | c.6717C>T p.S2239= (on ENST00000520002; = p.S2238= on NM_033225.6) | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as rs369976310; called by muse, mutect2, varscan2
- DCAF4L1 | c.1144C>T p.L382= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100295973; called by muse, mutect2, varscan2
- DNAH7 | c.5043A>C p.S1681= | Silent (SNP) | VAF 47/144 reads (33%) | catalogued as COSV56782608, COSV56784097; called by muse, mutect2, varscan2
- DOCK6 | c.2829G>A p.A943= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs764485752, COSV99626586; called by muse, mutect2, varscan2
- DSPP | c.2922C>T p.S974= | Silent (SNP) | VAF 26/178 reads (15%) | catalogued as rs753025274; called by muse, mutect2, varscan2
- FAM181B | c.1278C>T p.D426= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV61301075; called by muse, mutect2, varscan2
- GHSR | c.564C>T p.N188= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs752005705, COSV53838092; called by muse, mutect2, varscan2
- GLIPR1L1 | c.549C>T p.Y183= | Silent (SNP) | VAF 62/207 reads (30%) | catalogued as rs755736970, COSV56881178; called by muse, mutect2, varscan2
- GPR78 | c.69C>T p.N23= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs765752843, COSV66763847; called by muse, mutect2, varscan2
- IL1RAP | c.1662G>T p.R554= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs1416695786, COSV50770178; called by muse, mutect2, varscan2
- KCTD8 | c.357G>A p.A119= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV63595797; called by muse, mutect2, varscan2
- LMNB1 | c.1041G>A p.A347= | Silent (SNP) | VAF 45/127 reads (35%) | catalogued as rs202037109, COSV54399994; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRP1B | c.11484C>A p.R3828= | Silent (SNP) | VAF 79/208 reads (38%) | catalogued as COSV67270920; called by muse, mutect2, varscan2
- LZTS3 | c.78C>T p.S26= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs3746701; called by muse, mutect2, varscan2
- MATK | c.1476A>G p.S492= (on ENST00000310132 / NM_139355.3; = p.S493= on NM_002378.4) | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100036285; called by muse, mutect2
- MUC13 | c.1203G>A p.G401= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs745450880, COSV60701165; called by muse, mutect2, varscan2
- NAXE | c.672C>T p.D224= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as rs374015855; called by muse, mutect2, varscan2
- NLRP12 | c.705G>A p.A235= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs759713074, COSV60754655; called by muse, mutect2, varscan2
- PCDHGB3 | c.1338C>T p.N446= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV54024177; called by muse, mutect2, varscan2
- PCM1 | c.2841G>A p.K947= | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as COSV100279555; called by muse, mutect2, varscan2
- PEG3 | c.426C>T p.D142= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs766142792, COSV55643033; called by muse, mutect2
- PON3 | c.234G>A p.A78= | Silent (SNP) | VAF 49/114 reads (43%) | catalogued as rs377390399, COSV55697888; called by muse, mutect2, varscan2
- PRTG | c.549T>C p.T183= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV66840483; called by muse, mutect2
- PTCHD4 | c.900C>T p.F300= | Silent (SNP) | VAF 41/113 reads (36%) | catalogued as rs371607981; called by muse, mutect2, varscan2
- PTPRS | c.1821C>T p.P607= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs763617364, COSV53615889; called by muse, mutect2, varscan2
- SDK1 | c.1065G>A p.A355= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs769886680, COSV67361051, COSV67369890; called by muse, mutect2, varscan2
- SPATA31E1 | c.1509C>A p.P503= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100351042; called by muse, mutect2, varscan2
- SPTA1 | c.6000C>T p.H2000= | Silent (SNP) | VAF 48/141 reads (34%) | catalogued as COSV100934150, COSV63758730; called by muse, mutect2, varscan2
- SSH1 | c.1824C>T p.L608= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs1565969689, COSV58460110; called by muse, mutect2, varscan2
- TFAP2B | c.693C>T p.C231= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV99540814; called by muse, mutect2, varscan2
- TMEM259 | c.402C>T p.R134= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs774357446, COSV52263220; called by muse, mutect2, varscan2
- TRIP12 | c.2865A>G p.G955= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV52272280; called by muse, mutect2, varscan2
- ZNF257 | c.1287A>G p.K429= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs747947068, COSV71311688; called by muse, mutect2, varscan2
- DNAH8 | chr6:38723121 G>A | 5'Flank (SNP) | VAF 18/58 reads (31%) | catalogued as COSV59477917; called by muse, mutect2, varscan2
